TCGA case TCGA-EE-A20C — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc71a91d-8ad1-4bab-a4fa-89470aa4e4d0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 59 years; Vital status: Dead; Days to death: 4,601 days (12.6 years).

Diagnoses (25)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.5; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Classification of tumor: metastasis; Age at diagnosis: 71.5 years (26,129 days); Days to diagnosis: 4,469 days (12.2 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: I; Sites of involvement: Skin, Extremities.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.3 years (21,660 days); Year of diagnosis: 1997; AJCC staging edition: 4th; AJCC pathologic T: Tis; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 2,688 days (7.4 years); Days to treatment end: 2,716 days (7.4 years); Treatment dose: 48 Gy; Number of fractions: 20; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 4,458 days (12.2 years); Days to treatment end: 4,462 days (12.2 years); Treatment dose: 25 Gy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
4. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 59.7 years (21,802 days); Days to diagnosis: 142 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 147 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.
5. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Classification of tumor: Subsequent Primary; Age at diagnosis: 65.1 years (23,783 days); Days to diagnosis: 2,123 days (5.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 2,129 days (5.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 66.6 years (24,323 days); Days to diagnosis: 2,663 days (7.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,663 days (7.3 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
7. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Skin of scalp and neck. Age at diagnosis: 68.6 years (25,043 days); Days to diagnosis: 3,383 days (9.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 3,383 days (9.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
8. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 68.6 years (25,043 days); Days to diagnosis: 3,383 days (9.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 3,383 days (9.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
9. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 68.9 years (25,175 days); Days to diagnosis: 3,515 days (9.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 3,515 days (9.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
10. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 69.7 years (25,442 days); Days to diagnosis: 3,782 days (10.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 3,795 days (10.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
11. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 69.7 years (25,442 days); Days to diagnosis: 3,782 days (10.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 3,795 days (10.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
12. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Other ill-defined sites. Age at diagnosis: 70.3 years (25,687 days); Days to diagnosis: 4,027 days (11.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,027 days (11.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
13. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Skin of scalp and neck. Age at diagnosis: 70.3 years (25,687 days); Days to diagnosis: 4,027 days (11.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,027 days (11.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
14. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Upper limb, NOS. Age at diagnosis: 70.3 years (25,687 days); Days to diagnosis: 4,027 days (11.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,027 days (11.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
15. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Skin of scalp and neck. Age at diagnosis: 70.8 years (25,847 days); Days to diagnosis: 4,187 days (11.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,187 days (11.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
16. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Skin of other and unspecified parts of face. Age at diagnosis: 70.8 years (25,847 days); Days to diagnosis: 4,187 days (11.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,187 days (11.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
17. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Other ill-defined sites. Age at diagnosis: 70.8 years (25,847 days); Days to diagnosis: 4,187 days (11.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,187 days (11.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
18. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Penis, NOS. Age at diagnosis: 71.1 years (25,981 days); Days to diagnosis: 4,321 days (11.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,321 days (11.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
19. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 71.3 years (26,030 days); Days to diagnosis: 4,370 days (12.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 4,383 days (12.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
20. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 71.3 years (26,056 days); Days to diagnosis: 4,396 days (12.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
21. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of abdomen. Age at diagnosis: 71.3 years (26,056 days); Days to diagnosis: 4,396 days (12.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
22. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of thorax. Age at diagnosis: 71.3 years (26,056 days); Days to diagnosis: 4,396 days (12.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
23. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 71.3 years (26,056 days); Days to diagnosis: 4,396 days (12.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,410 days (12.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
24. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Pancreas, NOS. Age at diagnosis: 71.3 years (26,056 days); Days to diagnosis: 4,396 days (12.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
25. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Bone, NOS. Age at diagnosis: 71.5 years (26,101 days); Days to diagnosis: 4,441 days (12.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (21 entries)
- Day 2,663 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 2,663 days (7.3 years).
- Day 3,383 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 3,383 days (9.3 years).
- Day 3,383 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of scalp and neck; Days to progression: 3,383 days (9.3 years).
- Day 3,515 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 3,515 days (9.6 years).
- Day 3,782 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 3,782 days (10.4 years).
- Day 3,782 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 3,782 days (10.4 years).
- Day 4,027 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Other ill-defined sites; Days to progression: 4,027 days (11.0 years).
- Day 4,027 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 4,027 days (11.0 years).
- Day 4,027 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of scalp and neck; Days to progression: 4,027 days (11.0 years).
- Day 4,187 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Other ill-defined sites; Days to progression: 4,187 days (11.5 years).
- Day 4,187 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of other and unspecified parts of face; Days to progression: 4,187 days (11.5 years).
- Day 4,187 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of scalp and neck; Days to progression: 4,187 days (11.5 years).
- Day 4,321 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Penis, NOS; Days to progression: 4,321 days (11.8 years).
- Day 4,370 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 4,370 days (12.0 years).
- Day 4,396 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pancreas, NOS; Days to progression: 4,396 days (12.0 years).
- Day 4,396 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 4,396 days (12.0 years).
- Day 4,396 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 4,396 days (12.0 years).
- Day 4,396 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of abdomen; Days to progression: 4,396 days (12.0 years).
- Day 4,396 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to progression: 4,396 days (12.0 years).
- Day 4,441 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 4,441 days (12.2 years).
- Days to follow up: 4,601 days (12.6 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A20C-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A20C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-EE-A20C-06A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A20C-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: Right back; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A20C-06A-11D-A194-01): tumor purity 0.93, ploidy 3.55, whole-genome doublings 1.
